Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-5630, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-5630-01A (Primary Tumor).

[page 1 of 3]
TCGA-DQ-5630

HISTORY:

with recent diagnosis of squamous cell carcinoma of right lateral tongue. WLE right lateral tongue/hemiglossectomy right sentinel lymph node level I-IV.

GROSS:

1. "Lingual nerve" A 0.3 cm bit.
Frozen section control.)
2. "Hyoglossus" A 0.4 cm bit.
Frozen section control.)
3. "Genioglossus" A 0.5 cm bit.
Frozen section control.)
4. "Floor of mouth mucosa" A 2.8 cm bit.
Frozen section control.)
5. Received in formalin in a medium container is a partial glossectomy with one suture. No orientation. The suture presumably pointed to the anterior. Superior inked blue and inferior green. A 1.7 x 1.0 cm defect in the lateral surface. On the lateral tongue is a 2.5 x 1.2 x 3.2 cm, ill-defined, white mass, which appears to get close to the inked margin. The depth of invasion is 1.2 cm.
5A-B. Tumor with the deepest invasion.
5C-D.
6. "Right selective neck dissection level I" Received in formalin in a small container is a 9.2 x 5.0 cm fibroadipose tissue, which contains a 4.0 x 3.3 cm submental salivary gland with tan cut surface. Several lymph nodes identified.
6A. Several lymph nodes.
6B. One lymph node, bisected.
7. "Right selective neck dissection level II" Received in formalin in a small container is a 9 x 2.2 cm neck dissection which contains fibroadipose tissue and a fragment of skeletal muscle, 3.2 x 2.0 cm.
7A-C. Several lymph nodes. (Fat retained).
8. "Right selective neck dissection level III" Received in formalin in a small container is a 5 x 3.5 cm fibroadipose tissue. Several lymph nodes identified.
8A. Several lymph nodes.
8B-C. Each with two lymph nodes, one inked.
8D. One bisected lymph node.
9. "Right selective neck dissection level IV" Received in formalin in a small container is a 3.5 x 2.0 cm fibroadipose tissue. Several lymph nodes identified.
9A-B. Several lymph nodes. (Fat retained)

FROZEN SECTION REPORT

1. Nerve tissue, negative for carcinoma.
- 2-4. Negative for carcinoma.

I, , have reviewed and interpreted the frozen section material at the time it was requested.

I, have reviewed and interpreted the frozen section material at the time it was requested.

[page 2 of 3]
Permanent sections confirm frozen section reports.

MICROSCOPIC:

SQUAMOUS LESIONS OF HEAD & NECK: RESECTION

Site: Tongue. ✓

Findings: Squamous cell carcinoma. ✓

Differentiation: Moderate.

Subtype: N.A.

Gross: Ulcerating Size 3.2 cm (largest dimension).

Invasion: Present If present: depth 1.3 cm.

Tumor border: Infiltrative.

Perineural invasion: Present If present: Moderate.

Vascular invasion: Absent.

Bone/Cartilage invasion: N.A.

Lymphocyte infiltration: Present If present: Mild.

Margins: Negative.

SQUAMOUS LESIONS OF HEAD & NECK: LYMPH NODE DISSECTIONS

RIGHT LEVEL (or site)	#Positive	#Negative	Extracapsular extension
I	1	7	Absent
II	0	21	N.A.
III	0	14	N.A.
IV	0	6	N.A.
TOTAL	1	48	Present.

MICROSCOPIC DIAGNOSIS:

[page 3 of 3]
1-5. Right lateral tongue, wide local excision and intraoperative margins: Moderately-differentiated squamous cell carcinoma invading into tongue muscle (depth 1.3 cm). Perineural invasion present. Margins free of tumor. Please see template.

6. Lymph nodes, right neck, level I, dissection: Metastatic squamous cell carcinoma in one of eight lymph nodes (1/8). No extranodal extension.

7. Lymph nodes, right neck, level II, dissection: Twenty-one lymph nodes negative for neoplasm (0/21).

8. Lymph nodes, right neck, level III, dissection: Fourteen lymph nodes negative for neoplasm (0/14).

9. Lymph nodes, right neck, level IV, dissection: Six lymph nodes negative for neoplasm (0/6).

I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:r

Close

Source: NCI Genomic Data Commons file b40a1d94-cec9-45e8-b4cd-70d2968681bb (TCGA-DQ-5630.513C2EB1-0CB8-485E-8DC9-B282102E87DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).